Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q4, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q4-01A (Primary Tumor).

[page 1 of 4]
Accession:
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to: INPATIENT

Ref. Source:

Clinical Diagnosis & History:

- FNA (+) for papillary carcinoma, right thyroid nodule measuring 1.5 cm.

Specimens Submitted:

- 1: Right paratracheal node (fs)
- 2: Right superior mediastinal lymph node (fs)
- 3: Midline neck tissue
- 4: Right paratracheal tissue
- 5: Delphian node
- 6: Total thyroid

DIAGNOSIS:

1. Right paratracheal node (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.8cm.
Size of the largest metastatic focus: 0.050 cm.
Extranodal extension is not identified

2. Right superior mediastinal lymph node (fs):

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 2

3. Midline neck tissue, biopsy:

- Benign fibroadipose tissue.

4. Right paratracheal tissue:

- Benign fibroadipose tissue.

5. Delphian node:

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 1

6. Total thyroid:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

1CS-0-3
Carcinoma, papillary, thyroid 826013

Site: thyroid, NOS C73.9

fw
8/31/11

[page 2 of 4]
Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 1.3 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
Focal invasion

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Papillary microcarcinoma 1mm in the left lobe

Adenoma(s) (away from the carcinoma):
Not identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:
Identified
Two unremarkable parathyroid gland, one in each lobe.

Lymph Nodes:
Six benign lymph nodes (0/6)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out *** ;

Gross Description:

M.D.

1. The specimen is received fresh, labeled "right paratracheal node", and consists of a lymph node measuring 0.8 x 0.8 x 0.6 cm. The specimen is bisected and entirely frozen.

Summary of sections:
FSC - frozen section control

M.D.

[page 3 of 4]
2. The specimen is received fresh, labeled "left obturator lymph node", and consists of two lymph nodes measuring 1 x 0.6 x 0.5 cm and 1.2 x 0.5 x 0.4 cm. The lymph nodes are bisected and entirely frozen.

Summary of sections:
FSC – frozen section control

3. The specimen is received in formalin, labeled "midline neck tissue" and consists of a 1.5 x 1.2 x 0.5 cm fragment of fatty yellow soft tissue. Entirely submitted.

Summary of sections:
U - undesignated

M.D.

4. The specimen is received in formalin, labeled "right paratracheal tissue" and consists of a 0.8 x 0.7 x 0.5 cm fragment of fatty yellow soft tissue. Entirely submitted.

Summary of sections:
U - undesignated

D.

5. The specimen is received in formalin, labeled "Delphian node" and consists of a 0.7 x 0.7 x 0.5 cm fragment of fatty yellow soft tissue. The specimen is bisected and entirely submitted.

Summary of sections:
LN – lymph node

A.

6). The specimen is received in formalin, labeled "total thyroid, stitch marks right lobe" and consists of a 25 g thyroid. The right lobe measures 4.9 x 3.5 x 1.5 cm with an anteriorly attached 3.5 x 1.8 x 1.5 cm portion of muscle tissue. The left lobe measures 4 x 4 x 1.6 cm and the isthmus measures 2.3 x 1.6 x 0.5 cm. Attached to the left lobe is a 2 x 0.8 x 0.3 cm pyramidal lobe. The external surface is covered by a thin fibrous capsule. The specimen is previously inked posterior black and anterior blue. Sectioning reveals a 1.3 x 0.8 x 0.8 cm ovoid, tan-yellow, friable nodule with a less than 0.1 cm capsule in the right mid pole. The remaining thyroid parenchyma is red tan and meaty. A portion of the specimen is previously sent for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
RL - right lobe
LL - left lobe
PL - pyramidal lobe
IS - isthmus

Summary of Sections:

Part 1: Right paratracheal node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Right superior mediastinal lymph node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Midline neck tissue

[page 4 of 4]
Block	Sect. Site	PCs
1	u	1

Part 4: Right paratracheal tissue

Block	Sect. Site	PCs
1	u	1

Part 5: Delphian node

Block	Sect. Site	PCs
1	ln	1

Part 6: Total thyroid

Block	Sect. Site	PCs
2	IS	2
12	LL	12
2	PL	2
22	RL	22

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right paratracheal node (fs): A minute focus of metastatic thyroid carcinoma involving lymph node (Best seen in the initial frozen section slide, not the deeper FS slide). (Permanent diagnosis: Same)
2. Frozen section diagnosis: Right superior mediastinal lymph node (fs): Benign. (Permanent diagnosis: Same)

Source: NCI Genomic Data Commons file ce891fde-637b-445d-aa7a-42aaeefcbefa (TCGA-DJ-A2Q4.14A0CB22-0735-472B-910E-950B51DF9B1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).